Somatic mutation profile of tumor specimen 0DSEL7 from CCDI case PBCIAA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Desmoplastic small round cell tumor; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 13.9 years (5,066 days).
Specimen 0DSEL7: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f33c2c0-4861-4b50-b71e-0a5d5942a5d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSEKY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be76d658-6842-4654-b04d-4d8b43a26bfc

The open-access MAF lists 16 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Intron 2, 3'UTR 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DENND4B | c.2293C>T p.R765W | Missense Mutation (SNP) | VAF 103/349 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs755939763, COSV100768650, COSV63408073; called by muse, mutect2, varscan2
- FBXW10 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 112/514 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs567410950; called by muse, varscan2
- MYH7B | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 163/471 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV99482801; called by muse, mutect2, varscan2
- PCSK9 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 104/302 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs747072726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAAP20 | c.505C>A p.Q169K | Missense Mutation (SNP) | VAF 159/451 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.422); called by muse, mutect2
- KCNJ8 | c.698C>A p.T233K | Missense Mutation (SNP) | VAF 15/434 reads (3%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.975); called by muse, mutect2
- TRGC1 | c.470C>A p.T157N | Missense Mutation (SNP) | VAF 66/445 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by mutect2, varscan2
- ZNF541 | c.3013G>T p.E1005* | Nonsense Mutation (SNP) | VAF 57/180 reads (32%) | called by muse, mutect2, varscan2
- AFAP1L2 | c.810C>T p.S270= | Silent (SNP) | VAF 51/145 reads (35%) | catalogued as rs750679021, COSV58413188; called by muse, mutect2, varscan2
- HECW1 | c.2295C>T p.G765= | Silent (SNP) | VAF 85/294 reads (29%) | catalogued as rs756411752, COSV67835317; called by muse, mutect2, varscan2
- KCNC2 | c.1365C>T p.A455= | Silent (SNP) | VAF 18/384 reads (5%) | catalogued as rs1164791034, COSV54378190; called by muse, mutect2
- MEGF10 | c.1161C>T p.C387= | Silent (SNP) | VAF 30/613 reads (5%) | catalogued as COSV57251921; called by muse, mutect2
- AC026462.4 | n.481C>T | RNA (SNP) | VAF 61/209 reads (29%) | called by muse, mutect2, varscan2
- GCN1 | c.729+41C>T | Intron (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- OR10G7 | c.*6_*9del | 3'UTR (DEL) | VAF 55/148 reads (37%) | called by mutect2, pindel, varscan2
- SLC41A3 | c.1367-88C>A | Intron (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
